Gene-level copy-number profile of tumor specimen TCGA-AO-A12F-01A from TCGA case TCGA-AO-A12F, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 36.7 years (13,409 days).
Specimen TCGA-AO-A12F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.d36528cb-bb4a-4878-abf6-1709a1a0fb7e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A12F-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/389a5370-792b-423c-9604-feb0c6cf4d99

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 373; copy number 2: 3,734; copy number 3: 10,007; copy number 4: 11,091; copy number 5: 14,445; copy number 6: 5,148; copy number 7: 5,269; copy number 8: 3,295; copy number 9: 2,357; copy number 10: 2,340; copy number 11: 1,023; copy number 12: 444; copy number 13: 11; copy number 14: 89; copy number 18: 86; copy number 22: 64.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AO-A12F-01A-11D-A111-01): tumor purity 0.77, ploidy 5.22, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:21,383,801–25,926,808, 37 genes: RNA5SP337, AC130307.1, ANO5, AC116534.1, AC107882.1, AC107886.1, AC104009.1, SLC17A6, AC040936.1, LINC01495, AC055878.1, FANCF, GAS2, RNA5SP338, SVIP, AC006299.1, CCDC179, LINC02718, AC100767.2, WIZP1, MIR8054, AC100767.1, THAP12P4, AC068472.1, LINC02726, AC100768.1, RNU6-783P, AC099842.1, LINC02686, Y_RNA, LUZP2, AC115990.1, AC087373.1, RPL36AP40, AC100770.1, LINC02699, AC013799.1.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 1,717 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:202,999,738–248,919,946, 1,042 genes, copy number 11–12 (broad region; genes not listed).
- chr5:12,297,399–18,049,872, 100 genes, copy number 12–18 (broad region; genes not listed).
- chr5:50,396,192–50,934,521, 8 genes, copy number 13: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2.
- chr6:42,564,029–42,722,597, 3 genes, copy number 13 (within-gene range 7–13): UBR2, RNU6-890P, PRPH2.
- chr7:120,988,697–122,062,036, 14 genes, copy number 11: CPED1, HMGN1P18, RNA5SP241, RNU6-517P, AC006364.1, WNT16, FAM3C, CYCSP19, AC074085.1, AC074085.2, AC004875.1, RN7SKP277, PNPT1P2, PTPRZ1.
- chr11:66,744,451–71,252,577, 153 genes, copy number 14–22 (within-gene range 6–22) (broad region; genes not listed).
- chr12:66,767–10,674,318, 396 genes, copy number 11 (broad region; genes not listed).
- chr17:71,298,156–71,298,218, 1 gene, copy number 11: RNU7-155P.

Autosomal genes at a single copy (total copy number 1): 373. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
